Gene-level copy-number profile of tumor specimen TCGA-29-1784-01A from TCGA case TCGA-29-1784, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.3 years (20,210 days).
Specimen TCGA-29-1784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1799e1a3-740c-4f31-8278-9d80c60f699e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1784-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ef3455f-5b90-4ed5-b3aa-390f5f68bef3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,817; copy number 2: 16,048; copy number 3: 23,888; copy number 4: 10,152; copy number 5: 2,857; copy number 6: 2,796; copy number 7: 1,256.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1784-01A-02D-0559-01): tumor purity 0.72, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,256 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:191,199,241–191,398,659, 4 genes, copy number 7: OSTN, OSTN-AS1, UTS2B, CCDC50.
- chr3:191,461,163–191,461,456, 1 gene, copy number 7: PYDC2.
- chr7:141,074,064–148,420,998, 229 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:82,514,568–145,066,685, 977 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr16:46,469,341–48,156,018, 45 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12.

Autosomal genes at a single copy (total copy number 1): 2,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
